Somatic mutation profile of tumor specimen TCGA-60-2711-01A (aliquot TCGA-60-2711-01A-01W-0877-08) from TCGA case TCGA-60-2711, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.8 years (23,651 days).
Specimen TCGA-60-2711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53551e9c-c6b9-4982-be80-4a99f64495c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2711-11A (Solid Tissue Normal), aliquot TCGA-60-2711-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdc2a398-443b-4650-bd54-4856e8d11e88

The open-access MAF lists 121 somatic variants for this specimen: 79 protein-altering or splice-affecting, 34 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 34, Nonsense Mutation 8, Intron 4, RNA 4, Frame Shift Del 1, Splice Region 1, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC126283.2 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV67098616; called by muse, mutect2, varscan2
- ACKR2 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 265/897 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs760448133, COSV56177645; called by muse, mutect2, varscan2
- BEST4 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 114/160 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs752957577, COSV64733724; called by muse, varscan2
- BLM | c.551A>T p.Q184L | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV61924046; called by muse, mutect2, varscan2
- BPHL | c.875G>C p.*292Sext*21 | Nonstop Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV61318812, COSV61318987; called by muse, mutect2, varscan2
- BPTF | c.4537A>G p.K1513E | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV58837086; called by muse, mutect2, varscan2
- C3 | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55572786; called by muse, mutect2, varscan2
- CALCR | c.1448T>C p.I483T (on ENST00000649521 / NM_001164737.2; = p.I467T on NM_001742.4) | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV64008036; called by muse, mutect2
- CIART | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 103/960 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51744024; called by muse, mutect2, varscan2
- CNNM2 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV63998545; called by muse, mutect2, varscan2
- CNOT6 | c.1142C>G p.S381* | Nonsense Mutation (SNP) | VAF 50/138 reads (36%) | catalogued as COSV56161473; called by muse, mutect2, varscan2
- COL6A6 | c.2918G>T p.G973V | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV100650830, COSV62024971; called by muse, mutect2, varscan2
- CRACD | c.3381C>A p.V1127= | Splice Region (SNP) | VAF 73/141 reads (52%) | catalogued as COSV51720763, COSV99949035; called by muse, mutect2, varscan2
- CRTAC1 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54001482; called by muse, mutect2, varscan2
- CSMD3 | c.8941G>T p.G2981* (on ENST00000297405 / NM_001363185.1; = p.G2812* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV52177014; called by muse, mutect2, varscan2
- CSMD3 | c.4280T>A p.L1427* (on ENST00000297405 / NM_001363185.1; = p.L1323* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 36/165 reads (22%) | catalogued as COSV52177029; called by muse, mutect2, varscan2
- CST4 | c.404A>T p.N135I | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs1417068736, COSV54149633; called by muse, mutect2, varscan2
- CTNND2 | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 132/870 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58887977; called by muse, mutect2, varscan2
- CWH43 | c.831C>A p.Y277* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV56938755, COSV99894075; called by muse, mutect2, varscan2
- DAB2 | c.1751G>T p.W584L | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV57914288; called by muse, mutect2, varscan2
- DAB2 | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 74/491 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV57914299; called by muse, mutect2, varscan2
- DMWD | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV52178103; called by muse, mutect2, varscan2
- DMWD | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV52178110; called by muse, mutect2, varscan2
- DST | c.7085C>G p.S2362C | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.789); catalogued as COSV99753918; called by muse, mutect2, varscan2
- ENAM | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV68535911; called by muse, mutect2, varscan2
- FERD3L | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as rs745337460, COSV51762516, COSV51764115; called by muse, mutect2, varscan2
- GPRIN3 | c.809T>A p.L270H | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60884854; called by muse, mutect2, varscan2
- H1-8 | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV60711536; called by muse, mutect2, varscan2
- HCN1 | c.904A>T p.I302F | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV57509909; called by muse, mutect2, varscan2
- HERC2 | c.9633G>T p.E3211D | Missense Mutation (SNP) | VAF 43/391 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55323140; called by muse, mutect2, varscan2
- IFNE | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 28/38 reads (74%) | catalogued as rs1296446711, COSV58640927; called by muse, mutect2, varscan2
- IGSF3 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1265587019, COSV59590609; called by muse, mutect2, varscan2
- MON1A | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV56560481; called by muse, mutect2, varscan2
- MTNR1B | c.963G>T p.R321S | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV57065532, COSV57066467; called by muse, mutect2, varscan2
- NELL2 | c.562A>T p.T188S | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV61574625; called by muse, mutect2, varscan2
- NSUN2 | c.1097T>A p.V366E | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV52954269; called by muse, mutect2, varscan2
- OR2A5 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 280/710 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV68738629, COSV68738714; called by muse, varscan2
- OR2AG2 | c.425G>T p.W142L | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.515); catalogued as COSV58455122; called by muse, mutect2, varscan2
- OR4C15 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 142/696 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs750124773, COSV58952756; called by muse, varscan2
- PCDHA11 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); catalogued as rs991131905, COSV56499175; called by muse, mutect2, varscan2
- PGM5 | c.1284C>A p.H428Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV67167636; called by muse, mutect2, varscan2
- PHACTR3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs143288140, COSV63027760; called by muse, mutect2, varscan2
- PIK3CG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV63246379; called by muse, mutect2, varscan2
- PIK3R6 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs753549112, COSV61003102; called by muse, mutect2, varscan2
- PIP5KL1 | c.697C>A p.P233T (on ENST00000388747 / NM_001135219.2; = p.P30T on NM_173492.1) | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV55944494, COSV55944522; called by muse, mutect2, varscan2
- PLOD2 | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 5/124 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV51464737; called by muse, mutect2
- PLPPR4 | c.1781A>G p.K594R | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1467154077, COSV64565745; called by muse, mutect2, varscan2
- PRKCA | c.1404C>G p.N468K | Missense Mutation (SNP) | VAF 96/611 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52584362, COSV99434094; called by muse, mutect2, varscan2
- PTK2 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 176/1209 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749253117, COSV61785583; called by muse, mutect2, varscan2
- RNF213 | c.15206G>C p.R5069T | Missense Mutation (SNP) | VAF 71/91 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs746137859, COSV60396399, COSV60397215; called by muse, mutect2, varscan2
- RSC1A1 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV60779686; called by muse, mutect2, varscan2
- RXRG | c.1364T>C p.M455T | Missense Mutation (SNP) | VAF 97/460 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV63232102; called by muse, mutect2, varscan2
- SCLT1 | c.198C>G p.H66Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs936727509, COSV55405664; called by muse, mutect2, varscan2
- SLC6A8 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53472199; called by muse, mutect2, varscan2
- SLC7A2 | c.1147A>G p.K383E | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV50248327, COSV50252759; called by muse, varscan2
- SLC7A9 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as COSV50085094; called by muse, mutect2, varscan2
- SPAG17 | c.2143C>G p.P715A | Missense Mutation (SNP) | VAF 103/674 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV60458575, COSV60462861; called by muse, mutect2, varscan2
- SPANXN1 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 150/681 reads (22%) | catalogued as rs1480759110, COSV65122400; called by muse, mutect2, varscan2
- SPINT2 | c.309G>T p.R103S | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV56647840; called by muse, mutect2, varscan2
- SPTBN5 | c.8215G>A p.E2739K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.187); catalogued as COSV58020458; called by muse, mutect2, varscan2
- STYXL2 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.499); catalogued as rs758006721, COSV54804983; called by muse, mutect2
- TAS2R16 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 74/399 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99972217; called by muse, mutect2
- TBC1D10C | c.779T>G p.F260C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56702799; called by muse, mutect2, varscan2
- TEX10 | c.2566G>T p.E856* | Nonsense Mutation (SNP) | VAF 72/199 reads (36%) | catalogued as COSV52441877; called by muse, mutect2, varscan2
- TG | c.8059G>C p.D2687H | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV55075771; called by muse, mutect2, varscan2
- TOP2B | c.1039G>C p.V347L (on ENST00000264331 / NM_001330700.2; = p.V342L on NM_001068.3) | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV51971992; called by muse, mutect2, varscan2
- TRPM1 | c.4642C>G p.L1548V | Missense Mutation (SNP) | VAF 209/454 reads (46%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV56634348; called by muse, mutect2, varscan2
- UBE3A | c.1612G>T p.V538F | Missense Mutation (SNP) | VAF 54/547 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51665022; called by muse, mutect2
- USP31 | c.3971C>T p.P1324L | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as rs150676134; called by muse, mutect2, varscan2
- USP31 | c.3437A>G p.K1146R | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV54852079; called by muse, mutect2, varscan2
- VPS13A | c.8837G>A p.R2946K | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62429569; called by muse, mutect2, varscan2
- WDR49 | c.830A>T p.K277I (on ENST00000308378 / NM_001366158.1; = p.K618I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/655 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57708100; called by muse, mutect2
- ZNF100 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59747729; called by muse, mutect2, varscan2
- ZNF230 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs369515636; called by muse, mutect2, varscan2
- ZNF425 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65201296; called by muse, mutect2, varscan2
- ZNF711 | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52153908; called by muse, mutect2, varscan2
- COL1A2 | c.2463_2480del p.R822_P827del | In Frame Del (DEL) | VAF 44/312 reads (14%) | called by mutect2, pindel
- TP53 | c.792dup p.L265Tfs*7 | Frame Shift Ins (INS) | VAF 13/24 reads (54%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.2689_2691delinsTT p.P897Ffs*30 (on ENST00000343537 / NM_001031685.3; = p.P768Ffs*30 on NM_005426.2) | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2*
- ALKBH7 | c.586C>A p.R196= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV55532215; called by muse, mutect2
- ARHGEF17 | c.2244A>G p.E748= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV55232418; called by mutect2, varscan2
- ARL14 | c.549A>G p.G183= | Silent (SNP) | VAF 30/1069 reads (3%) | catalogued as COSV57899789; called by muse, mutect2
- ATP8A1 | c.1008C>A p.G336= | Silent (SNP) | VAF 73/362 reads (20%) | catalogued as COSV52534873, COSV52538002; called by muse, mutect2, varscan2
- CCDC18 | c.378G>A p.Q126= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as COSV58143366; called by muse, mutect2, varscan2
- CD226 | c.417C>T p.H139= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54612121; called by muse, mutect2, varscan2
- CNGA3 | c.1575C>A p.G525= | Silent (SNP) | VAF 77/227 reads (34%) | catalogued as COSV55624259; called by muse, mutect2, varscan2
- COL12A1 | c.6960C>A p.A2320= | Silent (SNP) | VAF 24/262 reads (9%) | catalogued as COSV59395785; called by muse, mutect2
- COL28A1 | c.1812G>A p.G604= | Silent (SNP) | VAF 188/488 reads (39%) | catalogued as COSV68082061; called by muse, mutect2, varscan2
- CSNK1D | c.381G>T p.R127= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs767499529, COSV53924418; called by muse, mutect2, varscan2
- DCAF12L2 | c.603C>G p.A201= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV63581609; called by muse, mutect2, varscan2
- DNAH3 | c.12180G>A p.L4060= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as COSV54520920; called by muse, mutect2
- FAM111A | c.1368A>T p.L456= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV64655341; called by muse, mutect2, varscan2
- FGA | c.1209G>A p.A403= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as rs775218633, COSV57394532; called by muse, mutect2, varscan2
- FLNA | c.2955T>A p.V985= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV61042777, COSV61048227; called by mutect2, varscan2
- IQCA1 | c.2325G>A p.A775= | Silent (SNP) | VAF 66/234 reads (28%) | catalogued as rs530031680, COSV54501773; called by muse, mutect2, varscan2
- JAKMIP2 | c.750G>T p.L250= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as COSV54604187; called by muse, mutect2
- KDM4D | c.1182G>C p.G394= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV58634568; called by muse, mutect2, varscan2
- KIF21A | c.315C>T p.N105= | Silent (SNP) | VAF 44/212 reads (21%) | catalogued as rs963047462, COSV62771263; called by muse, mutect2, varscan2
- LCT | c.5469C>A p.I1823= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as COSV51549068; called by muse, mutect2, varscan2
- NAA25 | c.2481A>G p.K827= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs112342385, COSV55704199; called by muse, mutect2, varscan2
- PCDH19 | c.3387G>T p.L1129= (on ENST00000373034 / NM_001184880.2; = p.L1081= on NM_020766.3) | Silent (SNP) | VAF 166/659 reads (25%) | catalogued as COSV55262635; called by muse, mutect2, varscan2
- POLE | c.5511G>T p.L1837= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV57680038; called by muse, mutect2, varscan2
- PRDM1 | c.2047C>A p.R683= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as COSV100958675; called by muse, mutect2, varscan2
- PRLR | c.1443C>T p.S481= | Silent (SNP) | VAF 185/424 reads (44%) | catalogued as COSV51495585; called by muse, mutect2, varscan2
- PRSS35 | c.1038C>T p.T346= | Silent (SNP) | VAF 43/220 reads (20%) | catalogued as COSV63800524; called by muse, mutect2, varscan2
- PTK2 | c.234G>A p.K78= | Silent (SNP) | VAF 174/1190 reads (15%) | catalogued as COSV61785592; called by muse, mutect2, varscan2
- RLN3 | c.135C>T p.F45= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV54600706; called by muse, mutect2, varscan2
- SPTB | c.2961G>A p.L987= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV67631729; called by muse, mutect2
- TTN | c.8973A>T p.T2991= (on ENST00000591111; = p.T2945= on NM_003319.4) | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV60050491; called by muse, mutect2, varscan2
- VEGFC | c.219C>G p.L73= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV54597996, COSV54605223; called by muse, mutect2, varscan2
- VEGFD | c.153G>A p.E51= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV52909583; called by muse, mutect2, varscan2
- ZMYND8 | c.9C>T p.I3= (on ENST00000311275 / NM_001363741.2; = p.I23= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/327 reads (15%) | catalogued as COSV53687399; called by muse, mutect2, varscan2
- ZNF251 | c.1944A>G p.K648= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1460381641, COSV52957323; called by muse, mutect2, varscan2
- ARHGAP24 | c.391+7170G>A | Intron (SNP) | VAF 67/228 reads (29%) | catalogued as rs140557900, COSV99981964; called by muse, mutect2, varscan2
- BCAS3 | c.2075-4918C>T | Intron (SNP) | VAF 73/383 reads (19%) | catalogued as COSV101175673; called by muse, mutect2, varscan2
- BTNL8 | c.787+118C>A | Intron (SNP) | VAF 60/252 reads (24%) | catalogued as COSV99180449; called by mutect2, varscan2
- FOLH1B | n.2067A>G | RNA (SNP) | VAF 60/106 reads (57%) | called by muse, mutect2, varscan2
- NXF5 | n.632C>A | RNA (SNP) | VAF 97/689 reads (14%) | catalogued as COSV53790886; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+710T>A | Intron (SNP) | VAF 66/192 reads (34%) | catalogued as COSV56890714, COSV99195166; called by muse, mutect2, varscan2
- SNORD115-21 | n.37G>T | RNA (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- SNORD115-33 | n.1G>T | RNA (SNP) | VAF 45/116 reads (39%) | catalogued as rs1267998159; called by muse, mutect2, varscan2
